CCDI case PBBSRF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/fd636433-3011-421c-8a65-3c9f09b4bc1f

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 3.2 years (1,156 days).

Biospecimens (3 samples)
- Sample 0DFXF2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFXFF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFXH2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
